Somatic mutation profile of tumor specimen C3N-04180-01 (aliquot CPT0247800006) from CPTAC case C3N-04180, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 71.0 years (25,948 days).
Specimen C3N-04180-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fb368e1-f6d8-4ee6-8b78-710208bbe66d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04180-31 (Blood Derived Normal), aliquot CPT0247840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05448b08-2390-40c1-88eb-364980594fbf

The open-access MAF lists 362 somatic variants for this specimen: 255 protein-altering or splice-affecting, 59 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 222, Silent 59, Intron 19, 3'UTR 11, Frame Shift Del 11, RNA 10, Splice Site 10, Nonsense Mutation 8, 5'UTR 5, 5'Flank 2, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 168/306 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 155/237 reads (65%) | catalogued as rs398123405, COSV58821297; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS13 | c.4039G>T p.G1347C | Missense Mutation (SNP) | VAF 224/313 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV52471477; called by muse, mutect2, varscan2
- ADGRL3 | c.4537C>A p.P1513T (on ENST00000506720 / NM_001322402.2; = p.P1402T on NM_015236.6) | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.01); catalogued as rs1169791045; called by muse, mutect2, varscan2
- AHNAK2 | c.1801G>A p.G601S | Missense Mutation (SNP) | VAF 127/360 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.028); catalogued as rs368235933; called by muse, mutect2, varscan2
- AIRE | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 227/322 reads (70%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs531220961; called by muse, mutect2, varscan2
- AOX1 | c.1497T>A p.N499K | Missense Mutation (SNP) | VAF 108/168 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs778010282; called by muse, mutect2, varscan2
- AQP8 | c.508C>A p.L170M | Missense Mutation (SNP) | VAF 86/432 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.247); catalogued as COSV54847842; called by muse, mutect2, varscan2
- ATM | c.8096C>T p.P2699L | Missense Mutation (SNP) | VAF 183/276 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM094666, COSV53742049, COSV53751122; called by muse, mutect2, varscan2
- ATP12A | c.1643G>A p.S548N | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99517540; called by muse, mutect2, varscan2
- CACNA1C | c.2288C>T p.T763I | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59781939; called by muse, mutect2, varscan2
- CACNA1H | c.229G>C p.A77P | Missense Mutation (SNP) | VAF 236/362 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1428706132; called by muse, mutect2, varscan2
- CASZ1 | c.4513G>A p.D1505N | Missense Mutation (SNP) | VAF 128/183 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs759093436; called by muse, mutect2, varscan2
- CCDC22 | c.228+1G>T p.X76_splice | Splice Site (SNP) | VAF 22/91 reads (24%) | catalogued as COSV59903433; called by muse, mutect2
- CCDC40 | c.1713G>T p.Q571H | Missense Mutation (SNP) | VAF 390/473 reads (82%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as COSV66473918, COSV66479696; called by muse, mutect2, varscan2
- CDC25C | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.879); catalogued as COSV60400332; called by muse, mutect2, varscan2
- CHRD | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 83/259 reads (32%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.483); catalogued as rs569589731; called by muse, mutect2, varscan2
- CRHBP | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 67/270 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as rs896528286, COSV57189697, COSV57190490; called by muse, mutect2, varscan2
- CYP3A4 | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60502246; called by muse, mutect2
- DHCR24 | c.947G>C p.R316P | Missense Mutation (SNP) | VAF 93/405 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV64874129; called by muse, mutect2, varscan2
- DPYS | c.1148C>A p.A383D | Missense Mutation (SNP) | VAF 127/552 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59827061; called by muse, mutect2, varscan2
- DPYS | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 97/904 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs962148202, COSV100679642, COSV60906475; called by muse, mutect2, varscan2
- DTHD1 | c.2198C>A p.S733* (on ENST00000456874; = p.S568* on NM_001136536.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/322 reads (3%) | catalogued as rs1313568784, COSV100678510, COSV62630464; called by muse, mutect2
- ESCO2 | c.1600G>T p.G534W | Missense Mutation (SNP) | VAF 163/501 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100533290; called by muse, mutect2, varscan2
- FAM47C | c.733C>A p.H245N | Missense Mutation (SNP) | VAF 170/581 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV63730760; called by muse, mutect2, varscan2
- FCGR3A | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs376334394, COSV100914646; called by muse, mutect2
- FER1L6 | c.621G>T p.M207I | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs199744134; called by muse, mutect2, varscan2
- FGFR2 | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 84/387 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV60659966; called by muse, mutect2, varscan2
- FSIP2 | c.14712del p.F4904Lfs*26 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs1179143773; called by pindel, varscan2
- GJA8 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 85/515 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as rs372038463; called by muse, mutect2, varscan2
- GRIPAP1 | c.1774-1G>A p.X592_splice | Splice Site (SNP) | VAF 191/363 reads (53%) | catalogued as COSV64552739; called by muse, mutect2, varscan2
- HECW1 | c.2214C>A p.D738E | Missense Mutation (SNP) | VAF 121/317 reads (38%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.012); catalogued as rs374095777; called by muse, varscan2
- HMCN1 | c.12274G>T p.V4092L | Missense Mutation (SNP) | VAF 99/469 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV54874349; called by muse, mutect2, varscan2
- IGKV1-16 | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 225/1252 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs768123675; called by muse, mutect2, varscan2
- IQCA1 | c.2329A>C p.T777P | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV54498565; called by muse, mutect2
- KL | c.2669A>G p.Y890C | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335409556; called by muse, mutect2, varscan2
- KLK5 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 78/344 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as COSV60451037; called by muse, mutect2, varscan2
- LAMA2 | c.7862G>T p.G2621V | Missense Mutation (SNP) | VAF 74/376 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM157848; called by muse, mutect2, varscan2
- LAYN | c.920G>T p.R307L (on ENST00000375615 / NM_001258390.1; = p.R299L on NM_178834.5) | Missense Mutation (SNP) | VAF 114/165 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs567971194, COSV65104819; called by muse, mutect2, varscan2
- LCE2C | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 181/442 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.649); catalogued as rs750400385, COSV100909433; called by muse, mutect2, varscan2
- LCE4A | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.038); catalogued as COSV59267210; called by muse, mutect2, varscan2
- LVRN | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs762129111, COSV100773704; called by muse, mutect2, varscan2
- NALCN | c.4873G>A p.A1625T | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1446700180; called by muse, mutect2, varscan2
- NEXMIF | c.1335C>G p.F445L | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT tolerated (0.28); PolyPhen benign (0.083); catalogued as COSV50021707; called by muse, mutect2, varscan2
- NHLH1 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 101/483 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1361488624, COSV57484393; called by muse, mutect2, varscan2
- NOTCH3 | c.5552G>C p.R1851P | Missense Mutation (SNP) | VAF 170/233 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54643479, COSV54649573; called by muse, mutect2, varscan2
- OR4K13 | c.775G>T p.V259F | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs199734457; called by muse, mutect2, varscan2
- OR51F1 | c.757del p.H253Mfs*13 | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | catalogued as COSV58579994; called by mutect2, pindel, varscan2
- OR5P2 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs779327457; called by muse, mutect2
- OR8K1 | c.27C>A p.H9Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.001); catalogued as COSV99687080; called by muse, mutect2, varscan2
- OR9K2 | c.252G>T p.M84I (on ENST00000305377; = p.M62I on NM_001005243.1) | Missense Mutation (SNP) | VAF 181/375 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs568585391, COSV100543915; called by muse, mutect2, varscan2
- PCDH15 | c.3907T>A p.Y1303N | Missense Mutation (SNP) | VAF 113/223 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV57409574; called by muse, mutect2, varscan2
- PCDHB12 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 74/121 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as COSV53399768; called by muse, mutect2, varscan2
- PCDHB14 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); catalogued as COSV53388601, COSV99505986; called by muse, mutect2, varscan2
- PCDHGA12 | c.431A>G p.E144G | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1363655439; called by muse, mutect2, varscan2
- PDHA2 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as COSV54780576; called by muse, mutect2, varscan2
- PDZRN3 | c.1037C>A p.T346K | Missense Mutation (SNP) | VAF 219/310 reads (71%) | SIFT tolerated (0.38); PolyPhen benign (0.06); catalogued as COSV55210659; called by muse, mutect2, varscan2
- PEX6 | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 81/414 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs370201505; called by muse, mutect2, varscan2
- PLCB4 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 94/127 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV53791968; called by muse, mutect2, varscan2
- PLEKHS1 | c.99+4_99+7del p.X33_splice (on ENST00000369310 / NM_182601.1; = p.X39_splice on NM_024889.5) | Splice Site (DEL) | VAF 151/332 reads (45%) | catalogued as rs777115891; called by mutect2, pindel, varscan2
- POTEJ | c.2026G>T p.G676C | Missense Mutation (SNP) | VAF 106/1019 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs750203790; called by muse, mutect2, varscan2
- PRDM9 | c.2476C>A p.H826N | Missense Mutation (SNP) | VAF 128/726 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57014058; called by muse, varscan2
- PTPRQ | c.4650A>T p.R1550S (on ENST00000616559; = p.R1508S on NM_001145026.2) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs376653087; called by muse, mutect2, varscan2
- RMDN3 | c.455C>G p.T152S | Missense Mutation (SNP) | VAF 175/360 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.54); catalogued as COSV53023467; called by muse, mutect2, varscan2
- RP1 | c.4346G>T p.G1449V | Missense Mutation (SNP) | VAF 81/337 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV99607304; called by muse, mutect2, varscan2
- RYR2 | c.12926T>A p.I4309N | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV100772023; called by muse, mutect2, varscan2
- SCGB1D2 | c.132_133del p.L46Cfs*4 | Frame Shift Del (DEL) | VAF 26/143 reads (18%) | catalogued as rs752710048; called by mutect2, pindel, varscan2
- SGO2 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as COSV100764572; called by muse, mutect2
- SH3TC2 | c.1408A>T p.I470L | Missense Mutation (SNP) | VAF 150/628 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs779447016; called by muse, mutect2, varscan2
- SLC12A1 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 75/142 reads (53%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.593); catalogued as rs1185924805; called by muse, mutect2, varscan2
- TENM4 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 78/316 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.026); catalogued as COSV53608038; called by muse, mutect2, varscan2
- TFB1M | c.942C>A p.D314E | Missense Mutation (SNP) | VAF 164/273 reads (60%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1562382279; called by muse, mutect2, varscan2
- THSD7B | c.3650G>T p.S1217I (on ENST00000272643; = p.S1215I on NM_001316349.2) | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99757477; called by muse, mutect2, varscan2
- TMEM82 | c.57G>T p.W19C | Missense Mutation (SNP) | VAF 72/99 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1416448729; called by muse, mutect2, varscan2
- TRPC4 | c.1523C>A p.S508Y | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100158283; called by muse, mutect2, varscan2
- TRPM1 | c.1348C>G p.R450G | Missense Mutation (SNP) | VAF 282/556 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.422); catalogued as COSV56630696, COSV99856888; called by muse, mutect2, varscan2
- TYR | c.962G>T p.C321F | Missense Mutation (SNP) | VAF 106/457 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as CM115207, COSV54485346; called by muse, mutect2, varscan2
- UNC13C | c.4386G>T p.Q1462H | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.135); catalogued as COSV52898959; called by muse, mutect2, varscan2
- VCAM1 | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781641145, COSV54118046; called by muse, mutect2, varscan2
- YBX2 | c.1029G>C p.Q343H | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.598); catalogued as rs1412569570; called by muse, mutect2, varscan2
- AADACL2 | c.90C>A p.S30R | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABL2 | c.1898G>T p.S633I (on ENST00000502732 / NM_007314.4; = p.S618I on NM_005158.5) | Missense Mutation (SNP) | VAF 173/427 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- ABLIM3 | c.542G>A p.C181Y | Missense Mutation (SNP) | VAF 100/203 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS6 | c.2143A>C p.T715P | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ADD3 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ADGRA1 | c.1455G>T p.E485D | Missense Mutation (SNP) | VAF 111/188 reads (59%) | SIFT tolerated (0.62); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ADGRF5 | c.3994A>T p.S1332C | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ADRA2A | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 19/32 reads (59%) | called by muse, varscan2
- AMER1 | c.2351C>A p.S784Y | Missense Mutation (SNP) | VAF 87/188 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ANGPT1 | c.370A>G p.T124A | Missense Mutation (SNP) | VAF 304/486 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2146C>A p.P716T | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AP2A2 | c.399C>G p.H133Q | Missense Mutation (SNP) | VAF 89/308 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- APEX2 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AQP9 | c.496-1G>T p.X166_splice | Splice Site (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- ATP8B4 | c.950A>C p.K317T | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.67); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATXN1L | c.1993G>T p.A665S | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT tolerated (0.89); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- BIK | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CACNA1S | c.1826A>T p.Q609L | Missense Mutation (SNP) | VAF 239/443 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN15 | c.2038G>T p.A680S | Missense Mutation (SNP) | VAF 224/359 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCNB3 | c.2945C>A p.P982H | Missense Mutation (SNP) | VAF 187/332 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- CELSR1 | c.226C>G p.R76G | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP65 | c.2406C>A p.N802K | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- CLEC12B | c.380T>G p.L127R | Missense Mutation (SNP) | VAF 82/201 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNST | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 115/198 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CPPED1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 82/279 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CSMD3 | c.9517dup p.C3173Lfs*16 (on ENST00000297405 / NM_001363185.1; = p.C3004Lfs*16 on NM_052900.3) | Frame Shift Ins (INS) | VAF 299/696 reads (43%) | called by mutect2, pindel, varscan2
- CSMD3 | c.7946T>A p.L2649* (on ENST00000297405 / NM_001363185.1; = p.L2545* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 101/324 reads (31%) | called by muse, mutect2, varscan2
- CXorf56 | c.396dup p.R133Tfs*17 (on ENST00000536133 / NM_001170570.2; = p.R147Tfs*17 on NM_022101.4) | Frame Shift Ins (INS) | VAF 68/127 reads (54%) | called by mutect2, pindel, varscan2
- DAB1 | c.1174G>T p.G392W (on ENST00000371231; = p.G359W on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/168 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DACH1 | c.1390G>T p.A464S (on ENST00000619232 / NM_001366712.1; = p.A412S on NM_080759.6) | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- DCC | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 122/353 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DCN | c.464T>A p.L155Q | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DENND1B | c.2152G>T p.G718C | Missense Mutation (SNP) | VAF 69/247 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- DNAH8 | c.7531G>T p.G2511W | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.2492G>T p.G831V | Missense Mutation (SNP) | VAF 87/360 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- DNAH9 | c.9896C>A p.A3299D | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNASE1 | c.113del p.M38Sfs*14 | Frame Shift Del (DEL) | VAF 91/524 reads (17%) | called by mutect2, pindel, varscan2
- DOCK2 | c.4882del p.R1628Gfs*24 | Frame Shift Del (DEL) | VAF 121/261 reads (46%) | called by mutect2, pindel, varscan2
- DPAGT1 | c.1168G>T p.G390C | Missense Mutation (SNP) | VAF 146/393 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DROSHA | c.1682G>T p.C561F | Missense Mutation (SNP) | VAF 49/265 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DSC3 | c.2274C>A p.N758K | Missense Mutation (SNP) | VAF 15/398 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by muse, mutect2
- EML5 | c.525+1G>T p.X175_splice | Splice Site (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- ERCC6 | c.2272G>T p.D758Y | Missense Mutation (SNP) | VAF 276/564 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ERVV-2 | c.1185G>T p.Q395H | Missense Mutation (SNP) | VAF 188/244 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ESCO2 | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 168/508 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM171A1 | c.2405G>T p.G802V | Missense Mutation (SNP) | VAF 100/138 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FAM20C | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); called by muse, varscan2
- FARP2 | c.294G>T p.W98C | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- FLT1 | c.3103G>C p.V1035L | Missense Mutation (SNP) | VAF 106/319 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FNDC1 | c.2795C>G p.T932R | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- FREM3 | c.2518T>A p.L840I | Missense Mutation (SNP) | VAF 108/368 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FXR1 | c.1422C>A p.S474R | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- GCN1 | c.6415G>C p.V2139L | Missense Mutation (SNP) | VAF 106/199 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- GIMAP1 | c.389A>T p.Q130L | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GOLGA6L22 | c.1350G>T p.E450D | Missense Mutation (SNP) | VAF 216/832 reads (26%) | SIFT tolerated (0.06); called by muse, varscan2
- GSG1L2 | c.311-1G>A p.X104_splice | Splice Site (SNP) | VAF 31/147 reads (21%) | called by muse, mutect2, varscan2
- GTF3C3 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 81/133 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- HEATR5A | c.1606A>T p.T536S | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HECW1 | c.2278C>A p.P760T | Missense Mutation (SNP) | VAF 44/347 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.011); called by muse, varscan2
- HGF | c.1390T>A p.C464S | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HNRNPA2B1 | c.1010G>T p.G337V (on ENST00000354667 / NM_031243.3; = p.G325V on NM_002137.4) | Missense Mutation (SNP) | VAF 227/483 reads (47%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- HOXD11 | c.709del p.A237Qfs*55 | Frame Shift Del (DEL) | VAF 45/123 reads (37%) | called by mutect2, pindel, varscan2
- IFITM2 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ITGAD | c.3023A>G p.Q1008R | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- KDM4C | c.1371T>G p.S457R | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, varscan2
- KIAA1210 | c.4315C>T p.Q1439* | Nonsense Mutation (SNP) | VAF 113/151 reads (75%) | called by muse, mutect2, varscan2
- KIR3DL1 | c.601C>A p.H201N | Missense Mutation (SNP) | VAF 71/318 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLF13 | c.842C>G p.T281S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- KRT75 | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 288/515 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP29-1 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 313/427 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- LAMA1 | c.9070G>T p.G3024C | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- LAMA1 | c.1495G>C p.G499R | Missense Mutation (SNP) | VAF 266/705 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LAS1L | c.1999C>A p.L667M | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- LIPI | c.1229A>G p.Q410R | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT tolerated (0.6); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- LMTK2 | c.3673C>G p.L1225V | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- LNPK | c.-62C>T | Splice Region (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.1906T>C p.Y636H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- LRRN1 | c.1090C>A p.R364S | Missense Mutation (SNP) | VAF 92/254 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- MACF1 | c.13917_13949del p.E4639_G4649del (on ENST00000372915; = p.E2572_G2582del on NM_012090.5) | In Frame Del (DEL) | VAF 56/307 reads (18%) | called by mutect2, pindel
- MAGEB4 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); called by muse, mutect2
- MAGEL2 | c.2787G>T p.Q929H | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MAP2K1 | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 80/276 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- MICAL3 | c.2899G>T p.V967L | Missense Mutation (SNP) | VAF 139/601 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); called by muse, varscan2
- MMP9 | c.556G>C p.G186R | Missense Mutation (SNP) | VAF 444/602 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH8 | c.2520G>T p.K840N | Missense Mutation (SNP) | VAF 173/338 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MYLK | c.3736G>T p.D1246Y | Missense Mutation (SNP) | VAF 173/235 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MYOCD | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- N6AMT1 | c.46C>A p.R16S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEUROG2 | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NIPBL | c.6027G>T p.L2009F | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NPIPB11 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 222/1490 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- OPRPN | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR2T5 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 80/616 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR2V2 | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 74/143 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- OR52A1 | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR5R1 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PARP1 | c.2728_2737del p.T910Efs*4 | Frame Shift Del (DEL) | VAF 40/243 reads (16%) | called by mutect2, pindel, varscan2
- PCDHA6 | c.1734C>A p.S578R | Missense Mutation (SNP) | VAF 230/949 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PCDHB8 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 251/1043 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.536); called by muse, varscan2
- PCDHGA12 | c.1139G>C p.G380A | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- PGAP4 | c.403del p.Q135Sfs*16 | Frame Shift Del (DEL) | VAF 115/206 reads (56%) | called by mutect2, pindel, varscan2
- PIGU | c.1186G>T p.V396F | Missense Mutation (SNP) | VAF 47/58 reads (81%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLCB4 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 62/98 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PLG | c.2018G>A p.S673N | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2
- PLXNB3 | c.3070G>T p.A1024S | Missense Mutation (SNP) | VAF 71/94 reads (76%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP1R36 | c.1000A>G p.K334E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- PTK2 | c.2696A>T p.N899I | Missense Mutation (SNP) | VAF 313/1172 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPDC1 | c.1626C>A p.S542R (on ENST00000375360 / NM_177995.3; = p.S594R on NM_152422.4) | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- RHOH | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 101/217 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RTP5 | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); called by muse, mutect2
- RYR2 | c.9677T>C p.I3226T | Missense Mutation (SNP) | VAF 120/247 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RYR3 | c.1728A>G p.I576M | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- S1PR5 | c.816G>T p.L272F | Missense Mutation (SNP) | VAF 104/331 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SCARA3 | c.1169A>T p.H390L | Missense Mutation (SNP) | VAF 109/251 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- SCARA5 | c.277del p.A93Pfs*2 | Frame Shift Del (DEL) | VAF 21/52 reads (40%) | called by mutect2, pindel, varscan2
- SEC24C | c.2446T>A p.C816S | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- SEPTIN10 | c.414-1G>T p.X138_splice | Splice Site (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- SHANK2 | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 122/260 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SHISA6 | c.866C>A p.S289* (on ENST00000409168 / NM_001173461.1; = p.S340* on NM_207386.4) | Nonsense Mutation (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- SIGLEC1 | c.3270G>T p.Q1090H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SIPA1L2 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC36A2 | c.1204C>A p.R402S | Missense Mutation (SNP) | VAF 82/312 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- SLC37A3 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 143/326 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- SLC4A10 | c.3208C>T p.P1070S (on ENST00000446997 / NM_001354461.2; = p.P1040S on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SMYD3 | c.531+1G>T p.X177_splice (on ENST00000490107 / NM_001375962.1; = p.X118_splice on NM_022743.2 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 132/282 reads (47%) | called by muse, mutect2, varscan2
- SNTG1 | c.461G>T p.C154F | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SNTG1 | c.1253C>A p.T418K | Missense Mutation (SNP) | VAF 82/219 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SOGA1 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SOS2 | c.1316G>T p.C439F | Missense Mutation (SNP) | VAF 304/447 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- SPATA31A6 | c.3631C>A p.Q1211K | Missense Mutation (SNP) | VAF 521/1600 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ST6GAL2 | c.1274C>G p.T425S | Missense Mutation (SNP) | VAF 75/171 reads (44%) | PolyPhen benign (0.145); called by muse, mutect2, varscan2
- SULF1 | c.30G>T p.L10F | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SV2A | c.1642A>T p.N548Y | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYCP2L | c.773T>C p.V258A | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TANC1 | c.5357C>A p.S1786Y | Missense Mutation (SNP) | VAF 139/255 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TCERG1L | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TEDC2 | c.649C>G p.Q217E | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TFAP2B | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 289/784 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFRC | c.797A>G p.E266G | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TLE6 | c.484C>A p.Q162K (on ENST00000246112 / NM_001143986.2; = p.Q39K on NM_024760.3) | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TLR3 | c.829A>T p.T277S | Missense Mutation (SNP) | VAF 118/230 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TMEM132C | c.3181A>T p.T1061S | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- TMEM132D | c.2362G>T p.V788F | Missense Mutation (SNP) | VAF 81/391 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- TMPRSS11A | c.53G>T p.W18L | Missense Mutation (SNP) | VAF 84/191 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPP2 | c.3415C>T p.Q1139* | Nonsense Mutation (SNP) | VAF 87/348 reads (25%) | called by muse, mutect2, varscan2
- TRANK1 | c.7477G>C p.E2493Q | Missense Mutation (SNP) | VAF 122/155 reads (79%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- TRAV8-4 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAV8-6 | c.5T>G p.L2R | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TRBV23-1 | c.50-1G>T p.X17_splice | Splice Site (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- TRIM24 | c.2207del p.P736Lfs*4 (on ENST00000343526 / NM_015905.3; = p.P702Lfs*4 on NM_003852.4) | Frame Shift Del (DEL) | VAF 14/103 reads (14%) | called by mutect2, pindel, varscan2
- TRIM49C | c.1178C>A p.T393N | Missense Mutation (SNP) | VAF 82/362 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRPA1 | c.2855T>A p.L952H | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPV6 | c.1924G>T p.V642L | Missense Mutation (SNP) | VAF 173/378 reads (46%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUBGCP5 | c.921+2T>A p.X307_splice | Splice Site (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.4034_4044del p.D1345Gfs*5 | Frame Shift Del (DEL) | VAF 40/238 reads (17%) | called by mutect2, pindel, varscan2
- UNC79 | c.4948G>T p.E1650* (on ENST00000393151 / NM_001346218.2; = p.E1473* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 44/138 reads (32%) | called by muse, mutect2, varscan2
- UPP2 | c.77A>G p.H26R | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- UQCRC1 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- WDR46 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 90/492 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR76 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- WNK3 | c.4096C>A p.H1366N | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WSCD2 | c.1404G>T p.W468C | Missense Mutation (SNP) | VAF 98/208 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XDH | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 103/484 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZBED3 | c.232C>G p.R78G | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZBED9 | c.3269C>G p.S1090C | Missense Mutation (SNP) | VAF 141/344 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZFR | c.2720G>T p.R907L | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF101 | c.1126G>T p.G376W | Missense Mutation (SNP) | VAF 64/102 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- ZNF101 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF215 | c.482A>T p.Q161L | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- ZNF32 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF516 | c.698A>G p.E233G | Missense Mutation (SNP) | VAF 113/339 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF578 | c.1357A>C p.K453Q | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ZNF681 | c.1151A>T p.H384L | Missense Mutation (SNP) | VAF 286/406 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- ZNF81 | c.667C>G p.H223D | Missense Mutation (SNP) | VAF 156/296 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZSCAN4 | c.504A>C p.E168D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- AP3B2 | c.300C>T p.Y100= | Silent (SNP) | VAF 73/241 reads (30%) | catalogued as rs781365751, COSV55606781; called by muse, mutect2, varscan2
- BCL2L10 | c.169C>A p.R57= | Silent (SNP) | VAF 38/188 reads (20%) | catalogued as rs770062586; called by muse, mutect2, varscan2
- CACNA1C | c.5568C>A p.P1856= | Silent (SNP) | VAF 172/340 reads (51%) | called by muse, mutect2, varscan2
- CFAP94 | c.1086T>C p.S362= (on ENST00000320267 / NM_001352064.2; = p.S368= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/105 reads (18%) | called by muse, mutect2, varscan2
- CYP3A4 | c.1248T>A p.P416= | Silent (SNP) | VAF 36/198 reads (18%) | called by muse, mutect2
- DBX2 | c.726G>C p.R242= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- DCANP1 | c.165C>A p.P55= | Silent (SNP) | VAF 79/144 reads (55%) | called by muse, mutect2, varscan2
- DTX4 | c.1308G>A p.K436= | Silent (SNP) | VAF 49/259 reads (19%) | called by muse, mutect2, varscan2
- DYRK2 | c.351G>T p.T117= (on ENST00000344096 / NM_006482.3; = p.T44= on NM_003583.4) | Silent (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- EMC7 | c.15G>C p.L5= | Silent (SNP) | VAF 25/41 reads (61%) | called by muse, mutect2, varscan2
- EP400 | c.6972G>A p.E2324= | Silent (SNP) | VAF 166/382 reads (43%) | catalogued as rs767429655; called by muse, mutect2, varscan2
- GPR45 | c.1113G>A p.A371= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs949071111, COSV51523431; called by muse, mutect2
- GRIK4 | c.2562G>A p.L854= | Silent (SNP) | VAF 82/253 reads (32%) | called by muse, mutect2, varscan2
- HECTD4 | c.1959G>C p.T653= | Silent (SNP) | VAF 65/238 reads (27%) | called by muse, mutect2, varscan2
- KCNJ4 | c.1212G>A p.E404= | Silent (SNP) | VAF 211/298 reads (71%) | called by muse, mutect2, varscan2
- KIAA0319 | c.1764T>A p.S588= | Silent (SNP) | VAF 76/181 reads (42%) | called by muse, mutect2, varscan2
- KIF20B | c.3822G>T p.L1274= (on ENST00000371728 / NM_001284259.2; = p.L1234= on NM_016195.4) | Silent (SNP) | VAF 53/217 reads (24%) | called by muse, mutect2, varscan2
- LIN7A | c.246C>G p.P82= | Silent (SNP) | VAF 119/248 reads (48%) | catalogued as COSV54023449, COSV54027996; called by muse, mutect2, varscan2
- MAGEL2 | c.354G>T p.P118= | Silent (SNP) | VAF 150/311 reads (48%) | catalogued as COSV58566157; called by muse, mutect2, varscan2
- MAP2 | c.3618G>A p.E1206= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs749797441; called by mutect2, varscan2
- MOAP1 | c.894C>T p.V298= | Silent (SNP) | VAF 56/141 reads (40%) | called by muse, mutect2, varscan2
- MS4A4A | c.639C>G p.T213= | Silent (SNP) | VAF 53/232 reads (23%) | called by muse, mutect2, varscan2
- MYH6 | c.3852C>A p.T1284= | Silent (SNP) | VAF 126/382 reads (33%) | catalogued as rs141143152; called by muse, mutect2, varscan2
- MYLK | c.4659G>A p.E1553= | Silent (SNP) | VAF 281/393 reads (72%) | called by muse, mutect2, varscan2
- MYO15B | c.5724A>T p.P1908= | Silent (SNP) | VAF 134/176 reads (76%) | called by muse, mutect2, varscan2
- NAA80 | c.348A>T p.A116= (on ENST00000417393 / NM_001200018.2; = p.A138= on NM_012191.4) | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- NBEAL2 | c.2310C>T p.S770= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as rs867290897, COSV52761319; called by muse, mutect2
- NEMP2 | c.987G>A p.L329= | Silent (SNP) | VAF 65/198 reads (33%) | called by muse, mutect2, varscan2
- NLRC4 | c.459C>T p.T153= | Silent (SNP) | VAF 63/123 reads (51%) | catalogued as COSV100707531; called by muse, mutect2, varscan2
- NME8 | c.1299C>A p.G433= | Silent (SNP) | VAF 226/437 reads (52%) | called by muse, mutect2, varscan2
- OR2V1 | c.600C>A p.L200= | Silent (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- OXR1 | c.291G>A p.G97= (on ENST00000442977 / NM_001198532.1; = p.G96= on NM_018002.3) | Silent (SNP) | VAF 144/242 reads (60%) | catalogued as COSV56330002; called by muse, mutect2, varscan2
- PASK | c.1398G>T p.G466= | Silent (SNP) | VAF 161/522 reads (31%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2013C>A p.G671= | Silent (SNP) | VAF 103/338 reads (30%) | catalogued as rs1554151115; called by muse, mutect2, varscan2
- PCDHB11 | c.1608C>T p.R536= | Silent (SNP) | VAF 177/1535 reads (12%) | catalogued as rs781934678, COSV61314124; called by muse, varscan2
- PCDHB15 | c.1659C>T p.D553= | Silent (SNP) | VAF 586/1087 reads (54%) | catalogued as COSV50858046; called by muse, mutect2, varscan2
- RADIL | c.1650G>T p.T550= | Silent (SNP) | VAF 89/284 reads (31%) | called by muse, mutect2, varscan2
- RNF187 | c.375G>A p.K125= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs1051643760; called by muse, mutect2, varscan2
- RPUSD2 | c.1203C>A p.G401= | Silent (SNP) | VAF 56/214 reads (26%) | called by muse, varscan2
- SLA | c.549A>T p.P183= (on ENST00000338087 / NM_001045556.3; = p.P223= on NM_006748.4) | Silent (SNP) | VAF 385/702 reads (55%) | called by muse, mutect2, varscan2
- SLITRK1 | c.966A>T p.T322= | Silent (SNP) | VAF 114/226 reads (50%) | called by muse, mutect2, varscan2
- SMARCA1 | c.1197A>T p.I399= | Silent (SNP) | VAF 112/343 reads (33%) | catalogued as COSV100946723; called by muse, mutect2, varscan2
- SPATA31A3 | c.3174C>A p.L1058= | Silent (SNP) | VAF 258/565 reads (46%) | catalogued as rs922098277; called by muse, mutect2, varscan2
- SPTBN5 | c.10542C>T p.H3514= | Silent (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- SYNE2 | c.8577C>T p.P2859= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as COSV59946988; called by muse, mutect2, varscan2
- SYT13 | c.897G>A p.P299= | Silent (SNP) | VAF 74/246 reads (30%) | catalogued as rs374760562; called by muse, mutect2, varscan2
- TET1 | c.5208C>T p.V1736= | Silent (SNP) | VAF 85/338 reads (25%) | catalogued as COSV65389564; called by muse, mutect2, varscan2
- TGFBR3 | c.2157G>A p.K719= | Silent (SNP) | VAF 126/180 reads (70%) | called by muse, mutect2, varscan2
- TMEM200C | c.495C>G p.L165= | Silent (SNP) | VAF 247/663 reads (37%) | called by muse, mutect2, varscan2
- TPTE2 | c.999C>A p.A333= (on ENST00000400230 / NM_199254.2; = p.A256= on NM_130785.3) | Silent (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- TRIM67 | c.324A>T p.T108= | Silent (SNP) | VAF 32/139 reads (23%) | called by muse, mutect2, varscan2
- TTYH1 | c.1239G>A p.L413= | Silent (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- TUBA3D | c.354C>A p.V118= | Silent (SNP) | VAF 98/232 reads (42%) | called by muse, varscan2
- VASH1 | c.957G>A p.K319= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- VCAN | c.4152C>T p.Y1384= | Silent (SNP) | VAF 26/144 reads (18%) | called by muse, mutect2, varscan2
- VSIG1 | c.789A>G p.A263= | Silent (SNP) | VAF 136/176 reads (77%) | called by muse, mutect2, varscan2
- WNT8A | c.885T>C p.T295= | Silent (SNP) | VAF 73/341 reads (21%) | called by muse, mutect2, varscan2
- ZFHX4 | c.1158G>C p.A386= | Silent (SNP) | VAF 65/187 reads (35%) | catalogued as COSV99256949; called by muse, mutect2, varscan2
- ZNF560 | c.519A>G p.R173= | Silent (SNP) | VAF 128/189 reads (68%) | called by muse, mutect2, varscan2
- ABCA1 | c.-25C>T | 5'UTR (SNP) | VAF 18/300 reads (6%) | catalogued as rs774301766; called by muse, mutect2
- ABCC8 | c.4411+11C>T | Intron (SNP) | VAF 86/240 reads (36%) | called by muse, mutect2, varscan2
- AC048338.2 | c.*50G>T | 3'UTR (SNP) | VAF 60/180 reads (33%) | catalogued as rs1305369729; called by muse, mutect2, varscan2
- AC244517.10 | c.36-4841G>T | Intron (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2
- ADAMTS17 | c.2950-29G>T | Intron (SNP) | VAF 119/243 reads (49%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851639 C>T | 3'Flank (SNP) | VAF 32/294 reads (11%) | called by muse, mutect2, varscan2
- AL603840.1 | n.816C>G | RNA (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- AP003062.1 | n.1027del | RNA (DEL) | VAF 117/228 reads (51%) | called by mutect2, pindel
- ARHGAP40 | c.*538G>T | 3'UTR (SNP) | VAF 79/244 reads (32%) | called by muse, mutect2, varscan2
- ARHGEF2 | c.2887+11G>C | Intron (SNP) | VAF 77/170 reads (45%) | called by muse, mutect2, varscan2
- BEST1 | c.-17C>A | 5'UTR (SNP) | VAF 108/443 reads (24%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*805C>T | 3'UTR (SNP) | VAF 66/114 reads (58%) | called by muse, mutect2, varscan2
- DCHS2 | n.3167G>C | RNA (SNP) | VAF 74/132 reads (56%) | catalogued as COSV59726555; called by muse, mutect2, varscan2
- DLG2 | c.205-65723C>T | Intron (SNP) | VAF 79/375 reads (21%) | catalogued as rs1567272429, COSV99720674; called by muse, mutect2, varscan2
- EYS | c.1767-7812G>T | Intron (SNP) | VAF 83/184 reads (45%) | called by mutect2, varscan2
- FGA | c.*6_*7insTAAGTGGGAATGGGAGCACTCTGTCTTC | 3'UTR (INS) | VAF 65/246 reads (26%) | catalogued as rs1553963837, COSV57393473; called by muse*, mutect2, pindel, varscan2*
- FLCN | c.871+68C>G | Intron (SNP) | VAF 173/682 reads (25%) | called by muse, mutect2, varscan2
- FOXI2 | c.-28G>C | 5'UTR (SNP) | VAF 66/270 reads (24%) | called by muse, mutect2, varscan2
- GPRC5A | c.981+15del | Intron (DEL) | VAF 114/224 reads (51%) | catalogued as rs769011846; called by pindel, varscan2
- HERC2P3 | n.1750T>C | RNA (SNP) | VAF 55/214 reads (26%) | called by muse, mutect2, varscan2
- IKZF1 | c.161-8252G>T | Intron (SNP) | VAF 56/329 reads (17%) | called by muse, mutect2, varscan2
- KRTAP2-2 | c.*134del | 3'UTR (DEL) | VAF 116/190 reads (61%) | called by mutect2, pindel, varscan2
- LAX1 | c.-171C>A | 5'UTR (SNP) | VAF 37/172 reads (22%) | called by muse, mutect2, varscan2
- LINC00479 | n.575G>C | RNA (SNP) | VAF 111/157 reads (71%) | called by muse, mutect2, varscan2
- MAP2 | c.4585-1556G>C | Intron (SNP) | VAF 118/222 reads (53%) | catalogued as rs143385469; called by muse, mutect2, varscan2
- MOCS2 | c.-655A>T | 5'UTR (SNP) | VAF 253/409 reads (62%) | called by muse, mutect2, varscan2
- MS4A4A | c.41+1954C>A | Intron (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2
- NAMPTP1 | n.384G>T | RNA (SNP) | VAF 16/381 reads (4%) | called by muse, mutect2
- NUTM1 | c.*132G>T | 3'UTR (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- OR52B1P | n.605T>A | RNA (SNP) | VAF 37/121 reads (31%) | called by muse, mutect2, varscan2
- PLEKHA3 | c.775+1222G>T | Intron (SNP) | VAF 33/57 reads (58%) | catalogued as rs1236583783; called by muse, mutect2, varscan2
- PUM1 | chr1:31065766 C>A | 5'Flank (SNP) | VAF 84/141 reads (60%) | called by muse, mutect2, varscan2
- RAE1 | c.1020+210del | Intron (DEL) | VAF 92/161 reads (57%) | called by mutect2, pindel, varscan2
- SCP2 | c.*37G>C | 3'UTR (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3191A>T | RNA (SNP) | VAF 80/399 reads (20%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2734C>T | RNA (SNP) | VAF 119/369 reads (32%) | called by muse, mutect2, varscan2
- SPNS1 | c.*37C>T | 3'UTR (SNP) | VAF 84/372 reads (23%) | called by muse, mutect2, varscan2
- SSX6P | n.51G>T | RNA (SNP) | VAF 160/296 reads (54%) | called by muse, mutect2, varscan2
- ST3GAL3 | c.348-15022G>T | Intron (SNP) | VAF 87/297 reads (29%) | called by muse, mutect2, varscan2
- TLL1 | c.*11T>G | 3'UTR (SNP) | VAF 55/301 reads (18%) | called by muse, mutect2, varscan2
- TRIM41 | c.1140+262T>G | Intron (SNP) | VAF 46/167 reads (28%) | called by muse, mutect2, varscan2
- TRIM5 | c.895+116T>G | Intron (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.34264+572G>T | Intron (SNP) | VAF 67/365 reads (18%) | catalogued as COSV100604075; called by muse, mutect2, varscan2
- TTR | c.*33G>T | 3'UTR (SNP) | VAF 111/443 reads (25%) | called by muse, mutect2, varscan2
- VAPB | c.*5053A>T | 3'UTR (SNP) | VAF 86/109 reads (79%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+5177G>T | Intron (SNP) | VAF 84/142 reads (59%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149777792 C>T | 5'Flank (SNP) | VAF 67/262 reads (26%) | catalogued as rs765025256; called by muse, mutect2, varscan2
- ZNF74 | c.121-979del | Intron (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel
